Somatic mutation profile of tumor specimen MP2PRT-PATBKT-TMP1-A (aliquot MP2PRT-PATBKT-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PATBKT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (697 days).
Specimen MP2PRT-PATBKT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cea38ed-a080-41f5-aae1-82d7ae4cb372.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATBKT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATBKT-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed3f62d3-92c5-4215-867a-b5b4055b9724

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Nonsense Mutation 4, Missense Mutation 4, Silent 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.176C>A p.A59E | Missense Mutation (SNP) | VAF 30/522 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55568979, COSV55604554, COSV55904854; called by muse, mutect2
- COX10 | c.1250G>A p.W417* | Nonsense Mutation (SNP) | VAF 31/599 reads (5%) | catalogued as rs750713909; called by muse, mutect2
- H2AC6 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 13/480 reads (3%) | catalogued as COSV100020137; called by muse, mutect2
- LRRC9 | c.2915C>A p.T972N | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.268); catalogued as rs774328450; called by muse, mutect2, varscan2
- NRDE2 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 16/548 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.088); catalogued as rs1327268148, COSV62962074; called by muse, mutect2
- TFAP4 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 24/727 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs1458961935; called by muse, mutect2
- IKZF3 | c.796C>T p.R266* | Nonsense Mutation (SNP) | VAF 17/340 reads (5%) | called by muse, mutect2
- RYR3 | c.1089G>A p.W363* | Nonsense Mutation (SNP) | VAF 12/420 reads (3%) | called by muse, mutect2
- MAGEB6 | c.261C>T p.N87= | Silent (SNP) | VAF 220/306 reads (72%) | catalogued as rs766167073, COSV100983842, COSV66871949; called by muse, mutect2, varscan2
- ROBO2 | c.2115G>A p.G705= | Silent (SNP) | VAF 16/495 reads (3%) | catalogued as rs1352237170; called by muse, mutect2
- TTC6 | chr14:37795289 C>T | 5'Flank (SNP) | VAF 69/222 reads (31%) | catalogued as COSV99942484; called by muse, mutect2, varscan2
